Somatic mutation profile of tumor specimen TCGA-H2-A2K9-01A (aliquot TCGA-H2-A2K9-01A-11D-A17V-08) from TCGA case TCGA-H2-A2K9, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 25.2 years (9,221 days).
Specimen TCGA-H2-A2K9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf7c4efa-cea4-4917-af7d-87d40a95f932.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-H2-A2K9-10A (Blood Derived Normal), aliquot TCGA-H2-A2K9-10A-01D-A17V-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e83c2c34-ef6e-40fe-8671-9d284083b59c

The open-access MAF lists 11 somatic variants for this specimen: 11 protein-altering or splice-affecting.
By variant classification: Missense Mutation 7, Nonsense Mutation 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 64/152 reads (42%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARAP3 | c.3011del p.A1004Vfs*16 | Frame Shift Del (DEL) | VAF 35/73 reads (48%) | catalogued as COSV53351928; called by mutect2, pindel, varscan2
- CST6 | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 13/117 reads (11%) | catalogued as COSV56409444; called by muse, mutect2
- DAPK1 | c.2035C>T p.R679* | Nonsense Mutation (SNP) | VAF 72/164 reads (44%) | catalogued as rs1276428726, COSV63785483; called by muse, mutect2, varscan2
- DMXL2 | c.846G>T p.Q282H | Missense Mutation (SNP) | VAF 69/120 reads (58%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.726); catalogued as COSV51842473; called by muse, mutect2, varscan2
- ESRP1 | c.1315C>T p.P439S | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as rs937205941, COSV64408408; called by muse, mutect2
- IGHG3 | c.1100C>T p.T367M | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as rs587764807; called by muse, mutect2, varscan2
- MYCBPAP | c.719A>T p.E240V | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60405980; called by muse, mutect2, varscan2
- NR4A2 | c.1379G>A p.G460D | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV59893065; called by muse, mutect2, varscan2
- PENK | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as rs376111422; called by muse, mutect2, varscan2
- PKDREJ | c.6204T>G p.Y2068* | Nonsense Mutation (SNP) | VAF 13/29 reads (45%) | catalogued as COSV53547411; called by muse, mutect2, varscan2
